Gene-level copy-number profile of tumor specimen HCM-CSHL-0178-C25-01A from HCMI case HCM-CSHL-0178-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 71.1 years (25,954 days).
Specimen HCM-CSHL-0178-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 822e0843-c0f3-4cfa-94ae-afe31ff6046b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0178-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/cc65e137-ed72-49fc-9128-9b4919fc59d3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 4; copy number 2: 10,537; copy number 3: 1,220; copy number 4: 40,785; copy number 5: 720; copy number 6: 4,214; copy number 7: 49; copy number 8: 75; copy number 9: 69; copy number 10: 556; copy number 11: 2; copy number 14: 38; copy number 15: 11; copy number 16: 3; copy number 18: 1; copy number 19: 35; copy number 27: 57.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr14:31,462,795–32,159,728, 14 genes: AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 770 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:138,819,954–139,302,551, 14 genes, copy number 14 (within-gene range 2–14): AC109927.1, AC109927.2, NOCT, ELF2, RNU6-531P, RN7SL382P, PPP1R14BP3, Metazoa_SRP, RN7SL311P, Y_RNA, RNU6-506P, RNU6-1074P, MGARP, NDUFC1.
- chr5:58,198–36,242,279, 535 genes, copy number 10 (broad region; genes not listed).
- chr5:41,868,975–45,895,970, 67 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr6:34,219,439–34,696,859, 14 genes, copy number 19 (within-gene range 2–19): CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25.
- chr6:34,889,255–35,428,191, 11 genes, copy number 15: ANKS1A, HSPE1P11, AL591002.1, AL138721.1, TCP11, SCUBE3, Z97832.2, ZNF76, Z97832.1, DEF6, PPARD.
- chr6:37,815,777–37,819,218, 1 gene, copy number 18: AL121574.1.
- chr6:39,048,781–39,115,186, 3 genes, copy number 16: GLP1R, SAYSD1, ANKRD18EP.
- chr6:39,934,595–40,587,364, 10 genes, copy number 14: TUBBP9, FO393411.1, AL139275.2, TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1.
- chr9:34,810,020–37,120,446, 92 genes, copy number 14–27 (broad region; genes not listed).
- chr14:31,100,112–31,207,804, 1 gene, copy number 9 (within-gene range 6–9): HECTD1.
- chr14:31,142,939–31,143,048, 1 gene, copy number 9: RNU6-541P.
- chr18:45,825,675–46,920,160, 21 genes, copy number 10 (within-gene range 2–10): SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
